Somatic mutation profile of tumor specimen C3N-01875-01 (aliquot CPT0117370007) from CPTAC case C3N-01875, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.7 years (24,349 days).
Specimen C3N-01875-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a1d12b4-e0ba-47ad-a065-c8973086b7de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01875-31 (Blood Derived Normal), aliquot CPT0117430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e006ec-3b95-4913-b1e0-0be243fd958c

The open-access MAF lists 596 somatic variants for this specimen: 398 protein-altering or splice-affecting, 117 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 267, Silent 117, Frame Shift Del 72, Intron 49, Frame Shift Ins 28, Nonsense Mutation 20, 3'UTR 12, RNA 6, 5'Flank 5, 3'Flank 5, 5'UTR 4, In Frame Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 131/292 reads (45%) | catalogued as rs1253151209, CM123456, COSV56236427; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 224/598 reads (37%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 22/71 reads (31%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ESR1 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 209/499 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as rs1057519714, COSV52784970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561dup p.Q521Pfs*30 | Frame Shift Ins (INS) | VAF 188/452 reads (42%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- IQSEC2 | c.4419del p.S1474Vfs*21 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, pindel
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 121/310 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PITX2 | c.344G>A p.R115H (on ENST00000354925 / NM_001204397.1; = p.R122H on NM_000325.6) | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs104893861, CM981540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 111/309 reads (36%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.465dup p.T156Yfs*6 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs1180724229; called by mutect2, varscan2
- AC099489.1 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as rs976516569; called by muse, mutect2, varscan2
- ACVR2A | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV99604571; called by muse, mutect2
- ADCK1 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 191/495 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765643989, COSV53086418; called by muse, mutect2, varscan2
- ADGRB1 | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV100029736; called by muse, mutect2, varscan2
- ADGRL4 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as rs1244238734; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AMER3 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762936709, COSV58465900, COSV58470726; called by muse, mutect2, varscan2
- AMPD3 | c.422C>T p.A141V (on ENST00000396553 / NM_001025389.2; = p.A150V on NM_000480.3) | Missense Mutation (SNP) | VAF 43/567 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67333145; called by muse, mutect2
- ANKFY1 | c.2072del p.P691Rfs*61 (on ENST00000341657 / NM_001330063.2; = p.P692Rfs*61 on NM_016376.5) | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as COSV58920130; called by mutect2, pindel, varscan2
- ARHGEF17 | c.4744G>A p.A1582T | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs780853835, COSV55234104; called by muse, mutect2
- ARID1A | c.1015del p.A339Lfs*24 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs1232964733; called by mutect2, pindel, varscan2
- ARID1A | c.6076C>T p.Q2026* | Nonsense Mutation (SNP) | VAF 150/393 reads (38%) | catalogued as COSV61374555; called by muse, mutect2, varscan2
- ARPC4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs779915246; called by muse, mutect2, varscan2
- ATP1A1 | c.297dup p.F100Vfs*17 | Frame Shift Ins (INS) | VAF 178/555 reads (32%) | catalogued as rs1360019202; called by mutect2, pindel, varscan2
- ATP6V0D1 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 125/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188030243; called by muse, mutect2, varscan2
- ATXN1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs758093377, COSV55209499; called by muse, mutect2, varscan2
- ATXN1L | c.295T>C p.S99P | Missense Mutation (SNP) | VAF 101/494 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1165601676; called by muse, mutect2, varscan2
- B3GAT3 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1297284187, COSV99641790; called by muse, mutect2
- BAZ2A | c.5233C>T p.R1745W | Missense Mutation (SNP) | VAF 135/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1252895343, COSV99464825; called by muse, varscan2
- BBC3 | c.670G>A p.D224N (on ENST00000449228 / NM_001127240.3; = p.E189= on NM_014417.5) | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV56262513; called by muse, mutect2, varscan2
- BPNT2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 210/507 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52907001; called by muse, mutect2, varscan2
- BRPF3 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1303979346; called by muse, varscan2
- BSN | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200764425; called by muse, mutect2, varscan2
- C9orf50 | c.1243A>G p.K415E | Missense Mutation (SNP) | VAF 133/311 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1287234913; called by muse, mutect2, varscan2
- CAD | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53032038; called by muse, mutect2
- CADM2 | c.637A>G p.T213A (on ENST00000407528 / NM_001167674.2; = p.T215A on NM_153184.4) | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV67378733; called by muse, mutect2, varscan2
- CALR | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 216/540 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1208070437; called by muse, mutect2, varscan2
- CBARP | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53068130; called by muse, mutect2, varscan2
- CCM2L | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1568910274, COSV99395434; called by muse, mutect2, varscan2
- CD4 | c.498dup p.K167Efs*13 | Frame Shift Ins (INS) | VAF 100/254 reads (39%) | catalogued as rs781937995; called by mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 87/248 reads (35%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH23 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374419277; called by muse, mutect2, varscan2
- CELF6 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs769547615, COSV54715476; called by muse, mutect2, varscan2
- CENPF | c.6761C>A p.S2254Y | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as COSV65273070; called by muse, mutect2, varscan2
- CFAP410 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 138/351 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1231631195, COSV57394250; called by muse, mutect2, varscan2
- CFP | c.1182dup p.C395Lfs*4 | Frame Shift Ins (INS) | VAF 142/453 reads (31%) | catalogued as rs1263452869; called by mutect2, pindel, varscan2
- CHIT1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs763988714, COSV55147519; called by muse, mutect2, varscan2
- CHST6 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 84/1163 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60001258; called by muse, mutect2
- CNTNAP5 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs374739161; called by muse, mutect2, varscan2
- COQ8A | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62012497; called by muse, mutect2
- CPXM2 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1334039190, COSV99580847; called by muse, mutect2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 232/652 reads (36%) | catalogued as rs747832403; called by mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCX | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM004409, COSV57573184; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 68/132 reads (52%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DMRTA2 | c.449del p.P150Rfs*65 | Frame Shift Del (DEL) | VAF 126/291 reads (43%) | catalogued as rs1219831517; called by mutect2, varscan2
- DMTN | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as rs539385159; called by muse, mutect2, varscan2
- DNAH5 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 180/464 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs375218798, CM124379, COSV54202866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJC14 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV57913424; called by muse, mutect2, varscan2
- DNAJC6 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs762410856, COSV54769895; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 59/168 reads (35%) | catalogued as rs772082432; called by mutect2, varscan2
- E2F1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 177/523 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622017, COSV58534885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF1 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV58176202; called by muse, mutect2
- EGFR | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 205/518 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV51785510, COSV51843325; called by muse, mutect2, varscan2
- EHHADH | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115181280; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 96/226 reads (42%) | catalogued as rs766700925; called by mutect2, varscan2
- EMP3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.347); catalogued as rs1002281659, COSV53159025; called by muse, mutect2, varscan2
- EMP3 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs749117341, COSV99507629; called by muse, mutect2
- EPB41 | c.2444G>A p.R815H (on ENST00000343067 / NM_001166005.2; = p.R539H on NM_004437.4) | Missense Mutation (SNP) | VAF 109/334 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762682968; called by muse, mutect2, varscan2
- FAM131B | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 189/479 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs200621437, COSV58369761; called by muse, mutect2, varscan2
- FAM155A | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1476528864, COSV65550352, COSV65556728; called by muse, varscan2
- FAM193A | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); catalogued as rs370673759, COSV61192691; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 141/395 reads (36%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM50B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV100976627; called by muse, mutect2, varscan2
- FBLN1 | c.142_144del p.K48del | In Frame Del (DEL) | VAF 266/738 reads (36%) | catalogued as rs775466355; called by mutect2, pindel, varscan2
- FEZF2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV99334821; called by muse, mutect2, varscan2
- FGD5 | c.3741G>A p.M1247I | Missense Mutation (SNP) | VAF 148/441 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs1288565456; called by muse, mutect2, varscan2
- GABRA5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 136/612 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs764850266, COSV100165668, COSV59483862; called by muse, mutect2, varscan2
- GDPD3 | c.573C>T p.A191= | Splice Region (SNP) | VAF 109/274 reads (40%) | catalogued as rs200801803, COSV53773211; called by muse, mutect2, varscan2
- GMEB2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs755628781, COSV56606079; called by muse, mutect2, varscan2
- GOLGA6B | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 41/213 reads (19%) | catalogued as rs1230578276; called by mutect2, varscan2
- GOLGA6D | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1367452872; called by mutect2, varscan2
- GPBAR1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1427424299, COSV50309336; called by muse, mutect2
- GPN1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773320443; called by muse, mutect2, varscan2
- GPR82 | c.130dup p.I44Nfs*3 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs35296655; called by mutect2, pindel, varscan2
- GSKIP | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1025603066, COSV68451346; called by muse, mutect2, varscan2
- H2BC15 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 30/623 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV57586559; called by muse, mutect2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 110/262 reads (42%) | catalogued as rs747537946; called by mutect2, varscan2
- HEATR5B | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 135/306 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV51858700; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HMMR | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs779134207, COSV62375130; called by muse, mutect2, varscan2
- HSD17B7 | c.759dup p.A254Cfs*10 | Frame Shift Ins (INS) | VAF 33/140 reads (24%) | catalogued as rs1162342283; called by mutect2, pindel, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 70/176 reads (40%) | catalogued as rs748943611; called by mutect2, varscan2
- ITPRIPL1 | c.1108del p.V370Cfs*11 (on ENST00000439118 / NM_001008949.3; = p.V378Cfs*11 on NM_178495.6) | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | catalogued as rs1439838873; called by mutect2, pindel, varscan2
- JRK | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 77/714 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV101401086; called by muse, mutect2, varscan2
- KANSL1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs763799758; called by muse, mutect2, varscan2
- KARS1 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 279/647 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs867340865, COSV56691747; called by muse, mutect2, varscan2
- KCNT1 | c.3621G>T p.Q1207H (on ENST00000488444; = p.Q1212H on NM_020822.3) | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53694893; called by muse, mutect2, varscan2
- KCTD10 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as COSV99949343; called by muse, mutect2
- KDM4B | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 163/405 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs539215011; called by muse, varscan2
- KIAA1109 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 120/259 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs749565576, COSV99174977; called by muse, mutect2, varscan2
- KIAA2026 | c.6026C>A p.S2009Y | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV67356615; called by muse, mutect2, varscan2
- KIF4B | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255083345; called by muse, mutect2
- KRTAP13-4 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV61879381; called by muse, mutect2, varscan2
- LAIR1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 144/354 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs149933025; called by muse, mutect2, varscan2
- LAMA5 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs549356678, COSV99442712; called by muse, mutect2, varscan2
- LAMB3 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs750121518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCE2B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 184/482 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs767189385, COSV64227613; called by muse, mutect2, varscan2
- MADD | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1161655712; called by muse, mutect2, varscan2
- MAST2 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.88); catalogued as rs768500557; called by muse, mutect2
- MEDAG | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1031639600; called by muse, mutect2, varscan2
- MEST | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs781873430, COSV104384440; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 224/597 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MINDY2 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs780697864; called by muse, mutect2, varscan2
- MKRN3 | c.171del p.F58Sfs*3 | Frame Shift Del (DEL) | VAF 54/310 reads (17%) | catalogued as COSV100091684; called by mutect2, pindel, varscan2
- MRPS11 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 273/694 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372417211; called by muse, mutect2, varscan2
- MRTFB | c.2629G>A p.A877T (on ENST00000571589 / NM_001365412.2; = p.A827T on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs150543121; called by muse, mutect2, varscan2
- MUC5AC | c.15130C>T p.L5044F | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100611567; called by muse, mutect2, varscan2
- MYH11 | c.5278C>T p.R1760C | Missense Mutation (SNP) | VAF 32/740 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764794087, COSV100260200; called by muse, mutect2
- MYLPF | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs375102609; called by muse, mutect2, varscan2
- MYO18B | c.5683C>T p.R1895C | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs368617132; called by muse, mutect2, varscan2
- MYO1B | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1353440626; called by muse, mutect2
- NAGPA | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 160/356 reads (45%) | PolyPhen probably damaging (0.98); catalogued as rs377424631; called by muse, mutect2, varscan2
- NCF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 73/810 reads (9%) | catalogued as rs1446986189, CM083736; called by muse, mutect2
- NCLN | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs757909399; called by muse, mutect2, varscan2
- NCOR2 | c.3904del p.H1302Mfs*12 | Frame Shift Del (DEL) | VAF 66/200 reads (33%) | catalogued as COSV100657106; called by mutect2, pindel, varscan2
- NFASC | c.934G>A p.G312R (on ENST00000339876 / NM_001378329.1; = p.G323R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100363245; called by muse, mutect2, varscan2
- NISCH | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs755940776, COSV99234741; called by muse, mutect2, varscan2
- NKX2-3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV60728716; called by muse, mutect2, varscan2
- NOTCH4 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1041758474, COSV66679525; called by muse, mutect2
- NPAP1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs751080271, COSV61507937; called by muse, mutect2, varscan2
- NR2C2AP | c.84del p.K28Nfs*22 | Frame Shift Del (DEL) | VAF 137/365 reads (38%) | catalogued as rs780246694; called by mutect2, pindel, varscan2
- NRXN2 | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1196436321; called by muse, mutect2
- NTN1 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs199736561; called by muse, mutect2, varscan2
- OGFR | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as rs376284025; called by muse, mutect2, varscan2
- OIT3 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as rs148064429; called by muse, mutect2, varscan2
- PCDH8 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs765239638; called by muse, mutect2, varscan2
- PCDHA6 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 117/1234 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV65343687; called by muse, mutect2
- PCDHB5 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 108/901 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554276140, COSV50668006; called by muse, mutect2, varscan2
- PDLIM4 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV53805310; called by muse, mutect2
- PEAR1 | c.3012del p.G1005Afs*57 | Frame Shift Del (DEL) | VAF 80/205 reads (39%) | catalogued as rs750264783; called by mutect2, pindel, varscan2
- PFKM | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 154/430 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56656230; called by muse, mutect2, varscan2
- PHYHIP | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.555); catalogued as rs746137577, COSV58688288; called by muse, mutect2, varscan2
- PHYKPL | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 115/327 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs745665429; called by muse, mutect2, varscan2
- PIEZO1 | c.3778G>A p.V1260I | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.992); catalogued as rs776788949, COSV56338250; called by muse, mutect2, varscan2
- PKHD1L1 | c.3901C>A p.P1301T | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV101006613; called by muse, mutect2, varscan2
- PLEKHG5 | c.1705C>T p.R569W (on ENST00000400915 / NM_001042663.3; = p.R532W on NM_020631.6) | Missense Mutation (SNP) | VAF 116/469 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756933610; called by muse, mutect2, varscan2
- PLPPR3 | c.934G>A p.D312N (on ENST00000520876 / NM_001270366.2; = p.D340N on NM_024888.2) | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as rs779560227; called by muse, mutect2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 75/211 reads (36%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PRB4 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.988); catalogued as rs747832494; called by muse, varscan2
- PRDM15 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 154/394 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as rs140958317; called by muse, mutect2, varscan2
- PRKCI | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs567380681; called by muse, mutect2, varscan2
- PROKR2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761425593, COSV54084959, COSV54084982; called by muse, mutect2, varscan2
- PTEN | c.96del p.I33Lfs*21 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as CM110156, COSV64298840; called by mutect2, pindel, varscan2
- PUF60 | c.1651C>T p.R551C (on ENST00000526683 / NM_001362896.2; = p.R534C on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1228265211, COSV100253133; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1499G>A p.S500N | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV50251127; called by muse, mutect2, varscan2
- RAB40A | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 215/577 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs764858205, COSV100420947; called by muse, mutect2, varscan2
- REC8 | c.827dup p.E277Gfs*85 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs766853930; called by mutect2, varscan2
- RELN | c.7843G>A p.D2615N | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs772130779; called by muse, mutect2, varscan2
- RGS19 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755556137; called by muse, mutect2, varscan2
- RNASEH1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.891); catalogued as rs1457543314; called by muse, mutect2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 75/189 reads (40%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROS1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs146130970, COSV63853614; called by muse, mutect2, varscan2
- RP1L1 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 183/411 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776156711, COSV66762092; called by muse, mutect2, varscan2
- RPA4 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100234319; called by muse, mutect2, varscan2
- RPS6KA6 | c.327dup p.A110Sfs*36 | Frame Shift Ins (INS) | VAF 34/118 reads (29%) | catalogued as rs756096568; called by mutect2, varscan2
- RPTOR | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 136/428 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1242627252; called by muse, mutect2, varscan2
- SERINC2 | c.1344_1346del p.L449del (on ENST00000373709 / NM_178865.5; = p.L453del on NM_018565.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 79/260 reads (30%) | catalogued as rs782765986; called by pindel, varscan2
- SH2B1 | c.1649G>A p.G550D | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451251; called by muse, mutect2, varscan2
- SHOX | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 239/677 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV100479353; called by muse, mutect2, varscan2
- SHROOM3 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 153/395 reads (39%) | catalogued as COSV56039840; called by muse, mutect2, varscan2
- SLC16A11 | c.827del p.G276Dfs*43 (on ENST00000308009; = p.G252Dfs*43 on NM_153357.3) | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | catalogued as COSV99080391; called by mutect2, varscan2
- SLC24A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1469280777; called by muse, mutect2, varscan2
- SLC45A2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 148/378 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.192); catalogued as rs201140684, COSV56872387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A17 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs534966872; called by muse, mutect2, varscan2
- SLCO2B1 | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1423565942; called by muse, mutect2, varscan2
- SLCO3A1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs775241468, COSV59230207; called by muse, mutect2, varscan2
- SPG11 | c.6175C>T p.R2059W | Missense Mutation (SNP) | VAF 182/452 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs755438310; called by muse, mutect2, varscan2
- SPTBN5 | c.4777del p.Q1593Kfs*57 | Frame Shift Del (DEL) | VAF 261/802 reads (33%) | catalogued as rs767702724; called by mutect2, pindel, varscan2
- SYNE3 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 239/640 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs750249553, COSV100515733; called by muse, mutect2, varscan2
- SYT7 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55657283; called by muse, mutect2, varscan2
- SYT8 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 135/288 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs747189922; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 58/148 reads (39%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TBX18 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs987207695, COSV63736139, COSV63737235; called by muse, mutect2, varscan2
- THBD | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 364/876 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs763736679, CM165190, COSV65702379; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs746975641; called by mutect2, varscan2
- TNFRSF9 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs776774122; called by muse, mutect2, varscan2
- TNS3 | c.3641C>T p.T1214M | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs763208423; called by muse, mutect2, varscan2
- TONSL | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776465152; called by muse, mutect2, varscan2
- TRERF1 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775958427, COSV61669969; called by muse, mutect2, varscan2
- TRIOBP | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 336/838 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.168); catalogued as rs779032542, COSV60375188; called by muse, mutect2, varscan2
- TRPV5 | c.1709T>C p.M570T | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755049082; called by muse, mutect2, varscan2
- TSPYL1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs979950673, COSV100889623; called by muse, mutect2
- TSPYL4 | c.182del p.G61Vfs*71 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as COSV60310254; called by mutect2, pindel, varscan2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 35/82 reads (43%) | catalogued as COSV104389590; called by mutect2, varscan2
- TTC28 | c.3014del p.G1005Afs*22 | Frame Shift Del (DEL) | VAF 73/378 reads (19%) | catalogued as COSV67414909; called by mutect2, pindel, varscan2
- U2AF1L4 | c.373C>T p.R125W (on ENST00000412391; = p.R86W on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1337714780; called by muse, mutect2
- U2SURP | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 42/141 reads (30%) | catalogued as COSV101204314, COSV101204495; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 78/206 reads (38%) | catalogued as rs1413847977; called by muse, mutect2, varscan2
- USP19 | c.3301A>G p.N1101D | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs780164404; called by muse, mutect2, varscan2
- UTP14C | c.2298_2299del p.*767Gfs*37 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs778876444; called by mutect2, pindel, varscan2
- VAC14 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 72/288 reads (25%) | catalogued as COSV55751200; called by muse, varscan2
- VAT1L | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as rs756454114; called by muse, mutect2, varscan2
- VCX | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 175/668 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.598); catalogued as rs767054222, COSV58233108; called by muse, varscan2
- VPS28 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs782803588, COSV52872124; called by muse, mutect2, varscan2
- VSX1 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 341/863 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV65021769; called by muse, mutect2, varscan2
- VWA5B1 | c.3247T>C p.S1083P (on ENST00000375079; = p.S1078P on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57058354; called by muse, mutect2, varscan2
- WFIKKN1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374779276; called by muse, mutect2, varscan2
- WNK4 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 158/454 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778048173; called by muse, mutect2, varscan2
- WRAP73 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 213/523 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs769227257, COSV54560009; called by muse, mutect2, varscan2
- XIRP1 | c.1288dup p.Q430Pfs*4 | Frame Shift Ins (INS) | VAF 83/285 reads (29%) | catalogued as rs1363271369; called by mutect2, pindel, varscan2
- ZAN | c.7405G>A p.G2469R | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370429370, COSV61814944; called by muse, mutect2, varscan2
- ZIC1 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 156/367 reads (43%) | catalogued as COSV51554018; called by muse, mutect2, varscan2
- ZNF132 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 114/314 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs530739078; called by muse, mutect2, varscan2
- ZNF197 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs368799335; called by muse, mutect2, varscan2
- ZNF668 | c.1543dup p.Q515Pfs*41 | Frame Shift Ins (INS) | VAF 50/144 reads (35%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF724 | c.1654_1658del p.H552Dfs*12 | Frame Shift Del (DEL) | VAF 110/335 reads (33%) | catalogued as rs1371198953; called by mutect2, pindel, varscan2
- ZNF804B | c.3746C>T p.S1249L | Missense Mutation (SNP) | VAF 127/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs368481408, COSV60818161, COSV60843135; called by muse, mutect2, varscan2
- ZNF821 | c.734G>A p.R245H (on ENST00000425432 / NM_001376297.1; = p.R203H on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 291/702 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748175590, COSV57987657; called by muse, mutect2, varscan2
- ZSWIM9 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752753509, COSV99619280; called by muse, mutect2, varscan2
- AEBP2 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ANKAR | c.4189dup p.S1397Ffs*? | Frame Shift Ins (INS) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.3927A>T p.E1309D | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD36C | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.494); called by muse, mutect2
- ANKRD44 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- AP2A1 | c.2551del p.Q851Rfs*5 | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP27 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP5 | c.1504del p.Y502Mfs*3 | Frame Shift Del (DEL) | VAF 39/131 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 63/172 reads (37%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 148/393 reads (38%) | called by mutect2, pindel, varscan2
- ARL13B | c.1003G>A p.D335N (on ENST00000394222 / NM_001174150.2; = p.D228N on NM_144996.4) | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ASIC1 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATAD2 | c.4030del p.S1344Vfs*15 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel
- ATG4A | c.126dup p.S43Ifs*2 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- ATP7A | c.4435A>G p.T1479A | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.06); called by muse, mutect2
- BCL3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- BEST4 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 170/442 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, varscan2
- BICC1 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICRAL | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- BRPF1 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C16orf89 | c.1073G>T p.R358M | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CADPS2 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- CARD16 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); called by muse, mutect2
- CBLC | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CCN1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 120/283 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCN2 | c.614_626del p.E205Vfs*22 | Frame Shift Del (DEL) | VAF 85/365 reads (23%) | called by mutect2, pindel, varscan2
- CCNB3 | c.261dup p.V88Sfs*20 | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1147del p.R383Afs*51 | Frame Shift Del (DEL) | VAF 55/193 reads (28%) | called by mutect2, pindel, varscan2
- CELF1 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CELSR1 | c.5317dup p.E1773Gfs*13 | Frame Shift Ins (INS) | VAF 167/500 reads (33%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 164/360 reads (46%) | called by mutect2, varscan2
- CHD6 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC16A | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CNPPD1 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A5 | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPSF1 | c.3354A>C p.K1118N | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CRTC1 | c.732del p.S245Pfs*5 | Frame Shift Del (DEL) | VAF 54/147 reads (37%) | called by mutect2, pindel, varscan2
- CTRB1 | c.185del p.G62Afs*40 | Frame Shift Del (DEL) | VAF 64/402 reads (16%) | called by pindel, varscan2
- CYP4F22 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 234/549 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- DBT | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 80/302 reads (26%) | called by muse, mutect2, varscan2
- DHX37 | c.2642G>T p.R881L | Missense Mutation (SNP) | VAF 123/315 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX58 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIO2 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 150/397 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH1 | c.8131C>T p.H2711Y | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAJC5G | c.436del p.C146Afs*47 | Frame Shift Del (DEL) | VAF 104/348 reads (30%) | called by mutect2, pindel, varscan2
- DNLZ | c.289_291del p.I97del | In Frame Del (DEL) | VAF 100/301 reads (33%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.1684G>A p.V562I (on ENST00000321322; = p.V502I on NM_020693.4) | Missense Mutation (SNP) | VAF 226/492 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DVL2 | c.869del p.G290Efs*11 | Frame Shift Del (DEL) | VAF 92/287 reads (32%) | called by mutect2, pindel, varscan2
- EIF4A3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- ERCC3 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ERVMER34-1 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 122/296 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- ESYT3 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYS | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- FER1L5 | c.6272C>T p.P2091L (on ENST00000623019; = p.P2055L on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); called by muse, mutect2
- GALC | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 159/482 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GDF2 | c.737del p.P246Qfs*27 | Frame Shift Del (DEL) | VAF 31/318 reads (10%) | called by mutect2, pindel, varscan2
- GRINA | c.333del p.N112Tfs*56 | Frame Shift Del (DEL) | VAF 46/135 reads (34%) | called by mutect2, pindel, varscan2
- GRIP1 | c.2747G>T p.R916M (on ENST00000359742 / NM_001379345.1; = p.R864M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); called by muse, mutect2
- GTDC1 | c.1342T>C p.S448P (on ENST00000344850 / NM_001354361.1; = p.S363P on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAX1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 65/144 reads (45%) | called by mutect2, varscan2
- HECTD4 | c.9228del p.T3077Pfs*79 | Frame Shift Del (DEL) | VAF 31/156 reads (20%) | called by mutect2, pindel
- HEY1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- HEY2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HIVEP2 | c.6783G>T p.E2261D | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLA-DRB1 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, varscan2
- HOXB4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 200/490 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HTR2B | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KANSL1 | c.2869del p.Q957Sfs*56 (on ENST00000574590 / NM_001193465.2; = p.Q958Sfs*56 on NM_015443.4) | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- KCNQ1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 139/312 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF3C | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KL | c.2801A>G p.Q934R | Missense Mutation (SNP) | VAF 118/277 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KLHL33 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 56/595 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- LAMC3 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 272/648 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LCAT | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGR6 | c.778C>T p.Q260* (on ENST00000367278 / NM_001017403.1; = p.Q208* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 58/155 reads (37%) | called by muse, mutect2, varscan2
- LPXN | c.321T>C p.V107= | Splice Region (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- LRRC25 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 51/560 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.151); called by muse, mutect2
- MADD | c.4541dup p.C1515Vfs*27 | Frame Shift Ins (INS) | VAF 42/126 reads (33%) | called by mutect2, pindel
- MAG | c.803del p.P268Rfs*4 | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | called by mutect2, pindel, varscan2
- MAPK1IP1L | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | called by mutect2, varscan2
- MARK4 | c.1446del p.N483Tfs*23 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by pindel, varscan2*
- MAST4 | c.7315C>T p.R2439W (on ENST00000403625 / NM_001164664.2; = p.R2250W on NM_015183.3) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MEX3D | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRC2 | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MRPS25 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 108/283 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MYBPC3 | c.3208dup p.Q1070Pfs*7 | Frame Shift Ins (INS) | VAF 44/157 reads (28%) | called by mutect2, pindel, varscan2
- MYBPC3 | c.2767C>A p.L923M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO1D | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 198/485 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NISCH | c.4082del p.P1361Lfs*203 | Frame Shift Del (DEL) | VAF 25/191 reads (13%) | called by mutect2, pindel, varscan2
- NMI | c.734del p.K245Sfs*15 | Frame Shift Del (DEL) | VAF 72/206 reads (35%) | called by mutect2, pindel, varscan2
- NPPC | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- NR6A1 | c.326G>T p.R109M (on ENST00000487099 / NM_033334.4; = p.R105M on NM_001489.5) | Missense Mutation (SNP) | VAF 190/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NXN | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OAS1 | c.388del p.R130Vfs*7 | Frame Shift Del (DEL) | VAF 58/159 reads (36%) | called by mutect2, pindel, varscan2
- OAS2 | c.574del p.R192Vfs*5 | Frame Shift Del (DEL) | VAF 51/149 reads (34%) | called by mutect2, pindel, varscan2
- OR1F1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.05); called by muse, mutect2
- OR8B4 | c.753dup p.G252Wfs*34 | Frame Shift Ins (INS) | VAF 78/236 reads (33%) | called by mutect2, pindel, varscan2
- OVOL1 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OXA1L | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 221/503 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- P2RY6 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 52/166 reads (31%) | called by mutect2, pindel, varscan2
- PCDHA1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 388/925 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCDHB9 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 167/460 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCSK6 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 136/360 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4DIP | c.4474del p.I1492Yfs*19 | Frame Shift Del (DEL) | VAF 82/231 reads (35%) | called by mutect2, pindel, varscan2
- PHEX | c.1612A>G p.N538D | Missense Mutation (SNP) | VAF 249/673 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF14 | c.1868_1870del p.Y623del | In Frame Del (DEL) | VAF 34/116 reads (29%) | called by pindel, varscan2
- PIAS4 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PIGQ | c.1223+1del | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- PKM | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PLD3 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK5 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTEN | c.878dup p.S294Kfs*4 | Frame Shift Ins (INS) | VAF 106/305 reads (35%) | called by mutect2, pindel, varscan2
- PWWP2B | c.563del p.P188Rfs*129 | Frame Shift Del (DEL) | VAF 57/171 reads (33%) | called by mutect2, pindel, varscan2
- QSOX1 | c.500del p.P167Hfs*24 | Frame Shift Del (DEL) | VAF 107/308 reads (35%) | called by mutect2, pindel, varscan2
- RAB14 | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RADIL | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RARS1 | c.1873+1G>C p.X625_splice | Splice Site (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2
- RPA1 | c.1087dup p.E363Gfs*4 | Frame Shift Ins (INS) | VAF 57/165 reads (35%) | called by mutect2, pindel, varscan2
- RTL1 | c.3752G>A p.G1251D | Missense Mutation (SNP) | VAF 104/474 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SCN5A | c.4299+1dup p.X1433_splice (on ENST00000333535 / NM_198056.3; = p.X1432_splice on NM_000335.5) | Splice Site (INS) | VAF 60/177 reads (34%) | called by mutect2, pindel, varscan2
- SH3RF3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SIM1 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- SIX5 | c.49del p.E17Rfs*91 | Frame Shift Del (DEL) | VAF 71/207 reads (34%) | called by mutect2, pindel, varscan2
- SLC22A31 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC22A31 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SLC36A3 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 95/261 reads (36%) | called by muse, mutect2, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, varscan2
- SND1 | c.79-2A>T p.X27_splice | Splice Site (SNP) | VAF 62/152 reads (41%) | called by muse, mutect2
- SOGA3 | c.1535dup p.A513Gfs*11 | Frame Shift Ins (INS) | VAF 34/94 reads (36%) | called by mutect2, varscan2
- SORCS3 | c.2306C>G p.A769G | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SPTBN5 | c.6173G>T p.C2058F | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SRM | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 191/444 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SRRM3 | c.1371-3C>T | Splice Region (SNP) | VAF 66/165 reads (40%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 131/327 reads (40%) | PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- STK4 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- STXBP5L | c.942G>C p.K314N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYCN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, varscan2
- TACC2 | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- TENM3 | c.5987T>A p.I1996N | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TIFA | c.489T>A p.Y163* | Nonsense Mutation (SNP) | VAF 91/222 reads (41%) | called by muse, mutect2, varscan2
- TMC6 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 25/460 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- TMCC3 | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM200C | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 239/639 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TMPO | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- TPRG1L | c.727del p.L243Cfs*23 | Frame Shift Del (DEL) | VAF 114/300 reads (38%) | called by mutect2, varscan2
- TRPM2 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRRAP | c.4121C>A p.A1374D | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TUBGCP6 | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TYW1 | c.1035dup p.R346Efs*3 | Frame Shift Ins (INS) | VAF 70/233 reads (30%) | called by mutect2, pindel, varscan2
- UBR4 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- UHRF1BP1 | c.1272_1273insTT p.L425Ffs*111 | Frame Shift Ins (INS) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- USP11 | c.1289C>T p.A430V (on ENST00000218348; = p.A387V on NM_001371072.1) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- VCP | c.1930T>C p.Y644H | Missense Mutation (SNP) | VAF 13/358 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- VPS13B | c.6200del p.L2067* | Frame Shift Del (DEL) | VAF 108/240 reads (45%) | called by mutect2, varscan2
- WAS | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- WDR81 | c.4126del p.V1376Cfs*24 (on ENST00000409644 / NM_001163809.2; = p.V325Cfs*24 on NM_152348.4) | Frame Shift Del (DEL) | VAF 77/221 reads (35%) | called by mutect2, pindel, varscan2
- WIPF1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 159/404 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WNK2 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- WWC2 | c.616del p.M206Cfs*17 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- XYLT2 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 134/283 reads (47%) | called by muse, mutect2, varscan2
- ZFHX3 | c.10285del p.R3429Vfs*56 | Frame Shift Del (DEL) | VAF 90/330 reads (27%) | called by pindel, varscan2
- ZFHX3 | c.10219del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 76/236 reads (32%) | called by pindel, varscan2
- ZFP64 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ZMIZ2 | c.2197del p.L733Cfs*60 | Frame Shift Del (DEL) | VAF 52/323 reads (16%) | called by mutect2, pindel, varscan2
- ZNF324B | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF438 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 156/403 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF644 | c.1399_1400del p.M467Dfs*16 | Frame Shift Del (DEL) | VAF 222/688 reads (32%) | called by pindel, varscan2
- ZNF688 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADAM21 | c.2043A>G p.G681= | Silent (SNP) | VAF 236/623 reads (38%) | called by muse, mutect2, varscan2
- ADO | c.246G>A p.L82= | Silent (SNP) | VAF 173/425 reads (41%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.672T>C p.T224= | Silent (SNP) | VAF 248/612 reads (41%) | called by muse, mutect2, varscan2
- BCAR3 | c.2007G>A p.L669= | Silent (SNP) | VAF 99/292 reads (34%) | catalogued as rs1425221421; called by muse, mutect2, varscan2
- BCL11B | c.2352C>T p.P784= (on ENST00000357195 / NM_001282237.2; = p.P713= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 196/470 reads (42%) | catalogued as rs1311997494; called by muse, mutect2, varscan2
- BDH2 | c.573C>T p.A191= | Silent (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- C11orf96 | c.78G>A p.T26= | Silent (SNP) | VAF 20/328 reads (6%) | catalogued as rs933359748; called by muse, mutect2
- CCNT2 | c.12C>T p.G4= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as rs370795827; called by muse, mutect2, varscan2
- CEBPE | c.489C>T p.G163= | Silent (SNP) | VAF 87/205 reads (42%) | catalogued as rs1251451886; called by muse, mutect2, varscan2
- CHRM3 | c.495C>T p.D165= | Silent (SNP) | VAF 93/262 reads (35%) | called by muse, mutect2, varscan2
- COL4A6 | c.3408C>T p.G1136= | Silent (SNP) | VAF 63/127 reads (50%) | called by muse, mutect2, varscan2
- COL5A1 | c.1263C>T p.Y421= | Silent (SNP) | VAF 135/315 reads (43%) | catalogued as rs373846823; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD2 | c.2214C>T p.S738= | Silent (SNP) | VAF 149/395 reads (38%) | catalogued as rs755074413, COSV99592657; called by muse, mutect2, varscan2
- CTSF | c.1140C>T p.S380= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs143674429; called by muse, mutect2, varscan2
- CUX1 | c.3870C>T p.N1290= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- CYP4F11 | c.910C>T p.L304= | Silent (SNP) | VAF 58/145 reads (40%) | called by muse, mutect2, varscan2
- DCAF15 | c.876C>T p.P292= | Silent (SNP) | VAF 146/345 reads (42%) | catalogued as rs532603322; called by muse, mutect2, varscan2
- DCUN1D2 | c.106A>C p.R36= | Silent (SNP) | VAF 200/564 reads (35%) | called by muse, mutect2, varscan2
- DISP2 | c.3642A>G p.P1214= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as rs35594441; called by muse, mutect2, varscan2
- DTX2 | c.462C>A p.V154= | Silent (SNP) | VAF 42/662 reads (6%) | called by muse, mutect2
- DUSP12 | c.123C>A p.A41= | Silent (SNP) | VAF 205/553 reads (37%) | called by muse, mutect2, varscan2
- ELANE | c.616T>C p.L206= | Silent (SNP) | VAF 171/431 reads (40%) | called by muse, mutect2, varscan2
- ELFN1 | c.828G>C p.P276= | Silent (SNP) | VAF 151/356 reads (42%) | catalogued as COSV101300309; called by muse, mutect2, varscan2
- ELOVL2 | c.294G>A p.Q98= | Silent (SNP) | VAF 110/340 reads (32%) | called by muse, mutect2, varscan2
- ERCC6 | c.2796T>C p.Y932= | Silent (SNP) | VAF 200/485 reads (41%) | called by muse, mutect2, varscan2
- FAT4 | c.1332C>T p.Y444= | Silent (SNP) | VAF 103/294 reads (35%) | catalogued as COSV67883786; called by muse, mutect2, varscan2
- FGFR1 | c.1179G>A p.S393= (on ENST00000447712 / NM_023110.3; = p.S391= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 184/551 reads (33%) | catalogued as rs374674165; called by muse, mutect2, varscan2
- FLI1 | c.966C>T p.G322= | Silent (SNP) | VAF 108/294 reads (37%) | catalogued as rs200962985; called by muse, mutect2, varscan2
- FRMPD2 | c.2784G>A p.P928= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs1389806056; called by mutect2, varscan2
- GFI1 | c.567C>T p.A189= | Silent (SNP) | VAF 195/428 reads (46%) | called by muse, mutect2, varscan2
- GNAI2 | c.789G>A p.T263= | Silent (SNP) | VAF 120/346 reads (35%) | catalogued as rs782512354; called by muse, mutect2, varscan2
- GOLGA3 | c.1665G>A p.T555= | Silent (SNP) | VAF 190/481 reads (40%) | catalogued as rs199984031; called by muse, mutect2, varscan2
- GPR6 | c.144C>T p.G48= | Silent (SNP) | VAF 218/567 reads (38%) | catalogued as rs1482045199, COSV51573222; called by muse, mutect2, varscan2
- GRIA4 | c.2178G>A p.L726= | Silent (SNP) | VAF 29/347 reads (8%) | called by muse, mutect2
- HDGFL3 | c.561C>T p.N187= | Silent (SNP) | VAF 79/205 reads (39%) | catalogued as rs750582778; called by muse, mutect2, varscan2
- HNRNPC | c.432T>A p.P144= (on ENST00000420743; = p.P131= on NM_004500.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 133/297 reads (45%) | catalogued as rs1422550385; called by muse, mutect2, varscan2
- IQGAP1 | c.3246C>T p.D1082= | Silent (SNP) | VAF 140/371 reads (38%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.687C>G p.P229= | Silent (SNP) | VAF 61/165 reads (37%) | called by muse, mutect2, varscan2
- IRX5 | c.891G>A p.A297= | Silent (SNP) | VAF 69/172 reads (40%) | called by muse, mutect2, varscan2
- KAT6A | c.3936C>T p.D1312= | Silent (SNP) | VAF 145/346 reads (42%) | catalogued as rs755916373, COSV55909080; called by muse, mutect2, varscan2
- KCNH2 | c.2214G>A p.Q738= | Silent (SNP) | VAF 44/514 reads (9%) | called by muse, mutect2
- KDM3B | c.3561A>G p.R1187= | Silent (SNP) | VAF 60/651 reads (9%) | called by muse, mutect2
- KMT2E | c.3765A>G p.S1255= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV57571322; called by muse, mutect2, varscan2
- LATS2 | c.672C>T p.P224= | Silent (SNP) | VAF 104/239 reads (44%) | catalogued as rs770391008; called by muse, mutect2, varscan2
- LHX5 | c.201C>T p.C67= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as rs1424763506, COSV99922361; called by muse, mutect2, varscan2
- LONP1 | c.2226G>A p.L742= | Silent (SNP) | VAF 129/339 reads (38%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1587G>A p.P529= | Silent (SNP) | VAF 107/288 reads (37%) | catalogued as COSV55475507; called by muse, mutect2, varscan2
- MAPK4 | c.1272C>T p.Y424= | Silent (SNP) | VAF 85/199 reads (43%) | catalogued as rs756972580; called by muse, mutect2, varscan2
- MAPK7 | c.1071T>C p.P357= | Silent (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- MARCHF7 | c.1816C>T p.L606= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs375171097; called by muse, mutect2, varscan2
- MGAT3 | c.1146C>T p.R382= | Silent (SNP) | VAF 131/319 reads (41%) | called by muse, mutect2, varscan2
- MLPH | c.255C>T p.G85= | Silent (SNP) | VAF 20/620 reads (3%) | called by muse, mutect2
- MXRA5 | c.6339G>A p.A2113= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs770918368, COSV99475388; called by muse, mutect2, varscan2
- MYH11 | c.1047G>A p.V349= | Silent (SNP) | VAF 171/487 reads (35%) | catalogued as rs765006823; called by muse, mutect2, varscan2
- MYH6 | c.1227C>T p.N409= | Silent (SNP) | VAF 56/634 reads (9%) | catalogued as rs752919716, COSV62453201; called by muse, mutect2
- MYO15A | c.8958C>T p.R2986= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2
- NFASC | c.3051G>A p.T1017= | Silent (SNP) | VAF 148/390 reads (38%) | catalogued as rs765463710; called by muse, varscan2
- NFATC1 | c.2118T>C p.T706= | Silent (SNP) | VAF 90/183 reads (49%) | called by muse, mutect2, varscan2
- NFXL1 | c.162C>T p.V54= | Silent (SNP) | VAF 134/382 reads (35%) | called by muse, mutect2, varscan2
- NID1 | c.312C>T p.V104= | Silent (SNP) | VAF 34/396 reads (9%) | catalogued as rs200949377; called by muse, mutect2
- NKAIN4 | c.42C>T p.C14= | Silent (SNP) | VAF 109/317 reads (34%) | catalogued as rs1316115744; called by muse, mutect2, varscan2
- NKX2-1 | c.708C>G p.G236= | Silent (SNP) | VAF 100/550 reads (18%) | catalogued as rs1219913571, COSV100701758; called by mutect2, varscan2
- NPHP4 | c.2559T>C p.D853= | Silent (SNP) | VAF 100/289 reads (35%) | catalogued as rs1022927409; called by muse, mutect2, varscan2
- NRAP | c.3588G>A p.S1196= (on ENST00000359988 / NM_001322945.2; = p.S1161= on NM_006175.4) | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as rs1564712095, COSV63491529; called by muse, mutect2
- ODF3L2 | c.633C>T p.D211= | Silent (SNP) | VAF 92/239 reads (38%) | catalogued as rs369746799; called by muse, varscan2
- OR52B4 | c.528T>C p.I176= | Silent (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1851G>A p.A617= | Silent (SNP) | VAF 24/624 reads (4%) | catalogued as rs1554129494, COSV65348934; called by muse, mutect2
- PF4 | c.43C>T p.L15= | Silent (SNP) | VAF 87/273 reads (32%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6927G>T p.G2309= | Silent (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.144G>A p.S48= | Silent (SNP) | VAF 90/402 reads (22%) | catalogued as rs545048958, COSV67337880; called by muse, mutect2, varscan2
- PLIN3 | c.681G>A p.Q227= | Silent (SNP) | VAF 117/337 reads (35%) | called by muse, mutect2
- PLXNA3 | c.1098C>A p.P366= | Silent (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- POTEF | c.102C>T p.C34= | Silent (SNP) | VAF 178/1050 reads (17%) | catalogued as rs1291597583; called by muse, mutect2, varscan2
- POU3F3 | c.111C>T p.G37= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- PRKACG | c.807G>A p.L269= | Silent (SNP) | VAF 32/431 reads (7%) | called by muse, mutect2
- PSD2 | c.612G>A p.A204= | Silent (SNP) | VAF 72/149 reads (48%) | catalogued as rs115268774, COSV51207171; called by muse, mutect2, varscan2
- PYY | c.147C>T p.Y49= | Silent (SNP) | VAF 128/310 reads (41%) | called by muse, mutect2, varscan2
- RAP1A | c.318G>A p.T106= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs757301118, COSV62728965; called by muse, mutect2, varscan2
- RFX2 | c.1890C>T p.R630= | Silent (SNP) | VAF 72/163 reads (44%) | called by muse, mutect2, varscan2
- ROBO2 | c.2997G>A p.T999= | Silent (SNP) | VAF 22/326 reads (7%) | catalogued as rs898400879, COSV100167229; called by muse, mutect2
- RTN4RL1 | c.1155G>A p.Q385= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- RUFY2 | c.1536T>C p.T512= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, varscan2
- SAC3D1 | c.400C>T p.L134= | Silent (SNP) | VAF 85/196 reads (43%) | catalogued as rs1461453236; called by muse, mutect2, varscan2
- SBK2 | c.705C>T p.P235= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1157337528; called by muse, mutect2, varscan2
- SERPINE3 | c.174C>A p.S58= | Silent (SNP) | VAF 151/416 reads (36%) | catalogued as COSV101246530; called by muse, mutect2, varscan2
- SIPA1L1 | c.3168C>T p.Y1056= | Silent (SNP) | VAF 28/350 reads (8%) | catalogued as rs775059651, COSV62173487; called by muse, mutect2
- SLC13A2 | c.192A>G p.L64= | Silent (SNP) | VAF 108/273 reads (40%) | catalogued as rs1555602631; called by muse, mutect2, varscan2
- SLC22A4 | c.456C>T p.G152= | Silent (SNP) | VAF 209/493 reads (42%) | catalogued as rs201822770, COSV52356800; called by muse, mutect2, varscan2
- SLC23A1 | c.1107C>T p.I369= | Silent (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- SLC26A3 | c.6T>C p.I2= | Silent (SNP) | VAF 129/357 reads (36%) | called by muse, mutect2, varscan2
- SLC9A2 | c.1146C>A p.T382= | Silent (SNP) | VAF 19/483 reads (4%) | catalogued as rs894966235; called by muse, mutect2
- SMPD2 | c.156T>C p.S52= | Silent (SNP) | VAF 127/311 reads (41%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2790G>A p.Q930= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs1158851160; called by muse, mutect2, varscan2
- SOX3 | c.1173C>T p.R391= | Silent (SNP) | VAF 111/265 reads (42%) | called by muse, mutect2, varscan2
- SPATS2 | c.66A>G p.V22= | Silent (SNP) | VAF 9/269 reads (3%) | called by muse, mutect2
- SRPX | c.474C>T p.T158= | Silent (SNP) | VAF 87/228 reads (38%) | catalogued as rs1387750678; called by muse, mutect2, varscan2
- SSTR4 | c.87G>A p.P29= | Silent (SNP) | VAF 78/142 reads (55%) | called by muse, mutect2, varscan2
- STAG3 | c.3111T>C p.H1037= | Silent (SNP) | VAF 117/264 reads (44%) | catalogued as rs992254234; called by muse, mutect2, varscan2
- TBC1D26 | c.12T>C p.D4= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as rs780875595; called by muse, mutect2, varscan2
- TCERG1L | c.726C>T p.T242= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs377139494, COSV64047479; called by muse, mutect2, varscan2
- TENM2 | c.4032C>T p.C1344= (on ENST00000518659 / NM_001122679.2; = p.C1105= on NM_001080428.3) | Silent (SNP) | VAF 57/553 reads (10%) | catalogued as rs754680231, COSV101319455; called by muse, mutect2
- TIAM2 | c.3585G>A p.A1195= | Silent (SNP) | VAF 79/239 reads (33%) | catalogued as rs201618143; called by muse, mutect2, varscan2
- TMEM199 | c.264A>G p.P88= | Silent (SNP) | VAF 50/128 reads (39%) | called by muse, varscan2
- TNC | c.3945C>T p.G1315= | Silent (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- TOP2B | c.3642A>G p.K1214= (on ENST00000264331 / NM_001330700.2; = p.K1209= on NM_001068.3) | Silent (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.672C>T p.F224= | Silent (SNP) | VAF 117/301 reads (39%) | catalogued as rs952810567; called by muse, mutect2, varscan2
- TRIM67 | c.1833A>G p.T611= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs772770270; called by muse, varscan2
- TRMT61B | c.129G>A p.S43= | Silent (SNP) | VAF 92/253 reads (36%) | catalogued as COSV100066821; called by muse, mutect2, varscan2
- TTN | c.92451G>A p.T30817= (on ENST00000591111; = p.T23393= on NM_003319.4) | Silent (SNP) | VAF 94/270 reads (35%) | catalogued as rs878887772, COSV100623173; called by muse, varscan2
- USP47 | c.2541C>T p.G847= (on ENST00000399455 / NM_001372095.1; = p.G759= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 91/215 reads (42%) | catalogued as rs199865903, COSV60462493; called by muse, mutect2, varscan2
- UTS2R | c.444C>A p.R148= | Silent (SNP) | VAF 33/357 reads (9%) | called by muse, mutect2
- VEGFD | c.384C>T p.T128= | Silent (SNP) | VAF 94/248 reads (38%) | called by muse, mutect2, varscan2
- WDR97 | c.1062C>T p.D354= | Silent (SNP) | VAF 173/461 reads (38%) | catalogued as rs574546652; called by muse, mutect2, varscan2
- ZC3H12D | c.645G>A p.E215= | Silent (SNP) | VAF 11/330 reads (3%) | called by muse, mutect2
- ZDBF2 | c.2781G>A p.V927= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- ZNF436 | c.1284C>A p.T428= | Silent (SNP) | VAF 39/299 reads (13%) | called by muse, mutect2, varscan2
- ZNF709 | c.489T>C p.T163= | Silent (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- ADAM32 | c.-19G>A | 5'UTR (SNP) | VAF 123/313 reads (39%) | called by muse, mutect2, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 14/150 reads (9%) | catalogued as rs779843196; called by pindel, varscan2*
- ADM2 | c.*52G>A | 3'UTR (SNP) | VAF 24/275 reads (9%) | catalogued as rs769729265; called by muse, mutect2
- ALDH1L1 | c.1983-28G>A | Intron (SNP) | VAF 27/58 reads (47%) | catalogued as rs770487415, COSV56418628; called by muse, varscan2
- ALDH1L1 | c.858+16T>G | Intron (SNP) | VAF 203/502 reads (40%) | called by muse, mutect2, varscan2
- ALKBH7 | c.*5del | 3'UTR (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- AP000769.3 | chr11:65501448 del T | 5'Flank (DEL) | VAF 45/127 reads (35%) | catalogued as rs746073535; called by mutect2, pindel, varscan2
- ARHGEF19 | c.1138-69G>A | Intron (SNP) | VAF 85/197 reads (43%) | catalogued as rs1026986173; called by muse, mutect2, varscan2
- ASH1L | chr1:155562817 T>A | 5'Flank (SNP) | VAF 149/385 reads (39%) | called by muse, mutect2, varscan2
- ASS1 | c.-5-222G>A | Intron (SNP) | VAF 195/441 reads (44%) | called by muse, mutect2, varscan2
- ATXN1 | c.-615+13398G>A | Intron (SNP) | VAF 51/173 reads (29%) | catalogued as rs1406693376; called by muse, mutect2, varscan2
- AVPR2 | chrX:153902685 A>G | 5'Flank (SNP) | VAF 70/194 reads (36%) | called by muse, mutect2, varscan2
- BOC | c.667+259G>A | Intron (SNP) | VAF 120/282 reads (43%) | catalogued as rs781575174; called by muse, mutect2, varscan2
- CIAO3 | c.162+72C>T | Intron (SNP) | VAF 66/127 reads (52%) | catalogued as rs1446061975; called by muse, mutect2, varscan2
- CMC1 | c.20-4del | Intron (DEL) | VAF 42/93 reads (45%) | catalogued as rs550932330; called by mutect2, varscan2
- CMSS1 | chr3:100185778 C>T | 3'Flank (SNP) | VAF 116/363 reads (32%) | catalogued as rs1014453081; called by muse, mutect2, varscan2
- COL18A1 | c.3928+664G>A | Intron (SNP) | VAF 79/427 reads (19%) | catalogued as rs1033783980; called by muse, varscan2
- COL9A1 | c.781-111C>T | Intron (SNP) | VAF 151/392 reads (39%) | called by muse, mutect2, varscan2
- CYTH1 | c.23-27012T>C | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as COSV63118866; called by muse, mutect2, varscan2
- DCAF17 | c.*888_*890del | 3'UTR (DEL) | VAF 82/260 reads (32%) | catalogued as rs1166150809; called by pindel, varscan2
- DGKB | c.2307+23G>A | Intron (SNP) | VAF 70/163 reads (43%) | catalogued as rs756428948; called by muse, mutect2, varscan2
- DNAJB5 | c.-35+703G>A | Intron (SNP) | VAF 187/472 reads (40%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+959C>T | Intron (SNP) | VAF 55/127 reads (43%) | called by muse, mutect2, varscan2
- DST | c.4297-2377C>T | Intron (SNP) | VAF 55/119 reads (46%) | catalogued as rs771032986; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC1I2 | c.871-9T>C | Intron (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- ERCC3 | c.1946-23C>T | Intron (SNP) | VAF 80/439 reads (18%) | called by muse, mutect2, varscan2
- FBLN1 | c.80-1076G>A | Intron (SNP) | VAF 117/294 reads (40%) | catalogued as rs372069245; called by muse, mutect2, varscan2
- FLNA | c.7156+25G>A | Intron (SNP) | VAF 119/301 reads (40%) | called by muse, mutect2, varscan2
- FLT4 | c.3893+810G>T | Intron (SNP) | VAF 129/339 reads (38%) | called by muse, mutect2, varscan2
- FMR1 | c.1471+20C>A | Intron (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- FXYD3 | c.-99+958del | Intron (DEL) | VAF 23/71 reads (32%) | catalogued as COSV100668755; called by mutect2, pindel, varscan2
- GABRD | c.-62G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- GRIA3 | c.2440-2661C>T | Intron (SNP) | VAF 24/386 reads (6%) | catalogued as COSV99991414; called by muse, mutect2
- GTF2IRD2P1 | n.1968G>A | RNA (SNP) | VAF 384/959 reads (40%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9741G>T | Intron (SNP) | VAF 70/374 reads (19%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-9del | Intron (DEL) | VAF 27/79 reads (34%) | catalogued as rs57800062, COSV61159208; called by mutect2, varscan2
- HPF1 | c.-10C>T | 5'UTR (SNP) | VAF 14/290 reads (5%) | catalogued as rs1444909778; called by muse, mutect2
- HSD17B1 | c.266-47C>T | Intron (SNP) | VAF 176/439 reads (40%) | called by muse, mutect2, varscan2
- IFT80 | c.778-10dup | Intron (INS) | VAF 35/119 reads (29%) | catalogued as rs1316973583; called by mutect2, pindel, varscan2
- IGFN1 | c.1242-2279del | Intron (DEL) | VAF 240/758 reads (32%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.738-10828dup | Intron (INS) | VAF 32/88 reads (36%) | catalogued as rs1326600994; called by mutect2, varscan2
- KHSRP | c.*698del | 3'UTR (DEL) | VAF 10/50 reads (20%) | catalogued as rs745860323; called by mutect2, varscan2
- KRT17P1 | n.730G>A | RNA (SNP) | VAF 238/957 reads (25%) | catalogued as rs1255140509; called by muse, mutect2, varscan2
- LARP7 | c.1142+107G>A | Intron (SNP) | VAF 36/88 reads (41%) | catalogued as rs1221615162; called by muse, mutect2
- LIPE | c.883+1973G>A | Intron (SNP) | VAF 23/241 reads (10%) | called by muse, mutect2
- MED17 | c.1585-28T>A | Intron (SNP) | VAF 43/376 reads (11%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397726 C>T | 3'Flank (SNP) | VAF 138/375 reads (37%) | called by muse, mutect2, varscan2
- MIR1302-7 | n.63del | RNA (DEL) | VAF 78/227 reads (34%) | catalogued as rs762308683; called by mutect2, pindel, varscan2
- MSH6 | c.261-1510del | Intron (DEL) | VAF 9/50 reads (18%) | catalogued as rs753923379; called by mutect2, varscan2
- NCKAP1 | c.3181-16T>C | Intron (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- NXF3 | c.*5C>A | 3'UTR (SNP) | VAF 116/335 reads (35%) | catalogued as rs1320200970; called by muse, mutect2, varscan2
- PLEKHG2 | c.883-14C>T | Intron (SNP) | VAF 62/150 reads (41%) | catalogued as rs1273705723; called by muse, mutect2, varscan2
- PON3 | c.495-51G>T | Intron (SNP) | VAF 84/193 reads (44%) | called by muse, mutect2, varscan2
- PTPN21 | c.*57del | 3'UTR (DEL) | VAF 82/274 reads (30%) | catalogued as rs748590887; called by mutect2, varscan2
- PTPRN2 | c.2344+5765G>A | Intron (SNP) | VAF 167/334 reads (50%) | catalogued as rs1340139130; called by muse, mutect2, varscan2
- RFPL4AP1 | n.432C>A | RNA (SNP) | VAF 44/907 reads (5%) | called by muse, mutect2
- RIMS2 | c.2084-956G>A | Intron (SNP) | VAF 90/222 reads (41%) | catalogued as rs544389984; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611318 del G | 5'Flank (DEL) | VAF 282/702 reads (40%) | catalogued as rs755358074; called by mutect2, varscan2
- RNF207 | c.324+295G>A | Intron (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- ROGDI | c.117+206C>T | Intron (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.*811C>T | 3'UTR (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- RRAS2 | c.-32G>T | 5'UTR (SNP) | VAF 65/289 reads (22%) | called by muse, mutect2, varscan2
- SEC31B | c.496-448T>C | Intron (SNP) | VAF 60/172 reads (35%) | called by muse, mutect2, varscan2
- SERP2 | c.158-1405C>T | Intron (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41909991 C>T | 3'Flank (SNP) | VAF 24/61 reads (39%) | catalogued as rs908335728; called by muse, mutect2, varscan2
- SKI | c.*49del | 3'UTR (DEL) | VAF 76/201 reads (38%) | catalogued as rs1322310334; called by mutect2, pindel, varscan2
- SLC22A7 | c.952-25A>T | Intron (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- SNORC | c.74-412_74-410delinsA | Intron (DEL) | VAF 19/51 reads (37%) | called by pindel, varscan2*
- SOCS2 | c.-213-837del | Intron (DEL) | VAF 30/90 reads (33%) | catalogued as rs768531990; called by mutect2, pindel
- SSTR5-AS1 | n.742G>T | RNA (SNP) | VAF 16/34 reads (47%) | catalogued as rs1175163163; called by muse, mutect2
- STK32B | c.108+291del | Intron (DEL) | VAF 16/43 reads (37%) | catalogued as rs759134987; called by mutect2, varscan2
- STX11 | c.*47C>T | 3'UTR (SNP) | VAF 94/227 reads (41%) | called by muse, mutect2, varscan2
- TMEM135 | chr11:87037871 C>G | 5'Flank (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- U82695.1 | n.1875del | RNA (DEL) | VAF 118/284 reads (42%) | called by mutect2, varscan2
- UNKL | c.852+25G>A | Intron (SNP) | VAF 103/267 reads (39%) | catalogued as rs372559366; called by muse, mutect2, varscan2
- USP15 | chr12:62417182 del G | 3'Flank (DEL) | VAF 59/99 reads (60%) | catalogued as rs766005728; called by mutect2, pindel, varscan2
- UVSSA | c.*9644A>G | 3'UTR (SNP) | VAF 332/824 reads (40%) | called by mutect2, varscan2
- VRK3 | chr19:49973104 G>A | 3'Flank (SNP) | VAF 82/196 reads (42%) | called by muse, mutect2, varscan2
- WDR19 | c.406+12C>T | Intron (SNP) | VAF 8/72 reads (11%) | catalogued as rs781438702; called by muse, mutect2
- ZCCHC24 | c.*33del | 3'UTR (DEL) | VAF 19/172 reads (11%) | catalogued as rs759518581; called by mutect2, pindel, varscan2
- ZNF827 | c.*507C>T | 3'UTR (SNP) | VAF 54/135 reads (40%) | catalogued as rs1243689882; called by muse, mutect2, varscan2
